Somatic mutation profile of tumor specimen TARGET-20-PARVZU-03A (aliquot TARGET-20-PARVZU-03A-01D) from TARGET case TARGET-20-PARVZU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 0.6 years (223 days).
Specimen TARGET-20-PARVZU-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 430e7250-23b6-4442-96ea-9d4da69ba4aa.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARVZU-14A (Bone Marrow Normal), aliquot TARGET-20-PARVZU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/430d646a-9e05-4431-84da-3d59afada63a

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 53/190 reads (28%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- CREBBP | c.3234_3238del p.Q1079Afs*6 | Frame Shift Del (DEL) | VAF 32/138 reads (23%) | called by mutect2, pindel, varscan2
